Surgical pathology report (de-identified scan), TCGA case TCGA-WB-A80M, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Erasmus MC, specimen TCGA-WB-A80M-01A (Primary Tumor).

Material:
Adrenal

Clinical data:
Pheochromocytoma? Status after adrenal resection.
Question: pathology? Pheo?
Description of material: right adrenal.

Macroscopy:

Fresh: adrenal, weight of 102 grams. Dimensions 8.5 x 6.5 x 4.15. Fragment is inked.
Frozen tumor tissue for research. Afterwards on formalin. Rest macro follows.

Adrenal with dimensions of 7.5 x 6.5 x 4.5 cm. The fragment has been split lengthwise and in its entirety gone through. Pre-existent adrenal tissue is not to recognize, it only relates to a sharp, rounded up, 5.3 cm wide, encapsulated tumor of a soft consistency. Central seems a star-shaped scar to be present. Macroscopically, the tumor is in its totality removed.
A number of five representative tumor sections with regard to the resection borders in cassette 1 / m 5. Partially 5b.

Microscopy

Intersections through adrenal containing a tumor consisting partly trabecular, partly located alveolar cells with small oval nuclei with salt and pepper chromatin and eosinophilic to clear cytoplasm. In addition, tumor contains areas with cells with enlarged, polymorphic nuclei, sometimes hyperchromatic, with large nucleoli and eosinophilic cytoplasm. No mitotic figures are seen. The tumor is surrounded by normal adrenocortical tissue and a wide capsule. Focally in growth into the capsule up to the cutting edge. No vaso-invasion. No in growth into the surrounding adipose tissue. There is no hyperplasia of the normal adrenal tissue. However, dilation of blood vessels is seen.

Additional research

Immunohistochemistry:
Chromogranin: scattered positive. S100 with sporadic positive cell.

Conclusion

Right adrenal resection: pheochromocytoma (5.3 cm), cutting edges tight free.

ICD-O-3
Pheochromocytoma NOS 8700/0
Site (R) Adrenal gland NOS
C74.9
Q4 10/17/13

HI/AA Discrepancy		✓

Source: NCI Genomic Data Commons file afe6cab8-0dca-4004-8a4b-b5b6e92b9165 (TCGA-WB-A80M.643C7E3A-C5D1-4E99-AF2C-612004EC8A0E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).